Somatic mutation profile of tumor specimen TCGA-AG-3591-01A (aliquot TCGA-AG-3591-01A-01D-1733-10) from TCGA case TCGA-AG-3591, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.2 years (24,167 days).
Specimen TCGA-AG-3591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5e3647-87b8-4485-949a-74bac1f3b3b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3591-10A (Blood Derived Normal), aliquot TCGA-AG-3591-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb61d34-92c2-46a6-83de-dc4c617f1c7d

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 50, Silent 20, Nonsense Mutation 6, Frame Shift Ins 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 17/33 reads (52%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/56 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 59/68 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3830C>T p.T1277M | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs374565343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC126283.2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs746566803, CM086803, COSV67099283; called by muse, mutect2, varscan2
- AMZ1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as rs528244160, COSV56688043; called by muse, mutect2, varscan2
- ANP32D | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 169/362 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1418004514, COSV56980080; called by muse, mutect2, varscan2
- ATCAY | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1181128566, COSV56657483; called by muse, mutect2, varscan2
- ATP6V1B1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 118/255 reads (46%) | catalogued as rs1553415274, COSV52266531; called by muse, mutect2, varscan2
- B3GNT7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005871; called by muse, mutect2, varscan2
- CELSR3 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 48/93 reads (52%) | catalogued as rs1290029544, COSV50911521, COSV51051760; called by muse, mutect2, varscan2
- CETN1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV59121761; called by muse, mutect2, varscan2
- CLEC4E | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV55226487; called by muse, mutect2, varscan2
- CTNNA3 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs779423519, COSV57717865, COSV57720911; called by muse, mutect2, varscan2
- DLGAP3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.046); catalogued as rs747689409, COSV52395602; called by muse, mutect2, varscan2
- DMD | c.4604C>T p.T1535M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431604157, COSV100822817, COSV63771742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB6 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as rs747467610, COSV99413069; called by muse, mutect2, varscan2
- FBN1 | c.5980G>T p.G1994W | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322950; called by muse, mutect2, varscan2
- FREM2 | c.2383G>A p.V795M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs369187680; called by muse, mutect2, varscan2
- FSTL5 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 59/187 reads (32%) | catalogued as rs776031059, COSV60209083; called by muse, mutect2, varscan2
- GPR6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51571736; called by muse, mutect2, varscan2
- GPRASP2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59991928; called by muse, mutect2, varscan2
- HHATL | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60042571; called by muse, mutect2, varscan2
- HOXD12 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV66832292; called by muse, mutect2, varscan2
- HSPG2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs779841547, COSV65973965; called by muse, mutect2, varscan2
- ITGAL | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs765514196, COSV100776185; called by muse, mutect2, varscan2
- KCNJ13 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503972, COSV52085606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAD1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs138881525; called by muse, mutect2, varscan2
- LCLAT1 | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100092363; called by muse, mutect2, varscan2
- LRP1B | c.6595A>C p.S2199R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV67246918; called by muse, mutect2, varscan2
- MACF1 | c.11405C>T p.P3802L (on ENST00000372915; = p.P1735L on NM_012090.5) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99243227; called by muse, mutect2, varscan2
- MYO7B | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as COSV67349247; called by muse, mutect2, varscan2
- NF2 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV58523024, COSV58526600; called by muse, mutect2, varscan2
- NPFFR2 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100440547, COSV58150261; called by muse, mutect2, varscan2
- NRG3 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as COSV64572238; called by muse, mutect2, varscan2
- OR6A2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60265382; called by muse, mutect2, varscan2
- PCDH11X | c.2236T>A p.L746I | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53483746; called by muse, mutect2, varscan2
- PEX13 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV54370740; called by muse, mutect2, varscan2
- RB1CC1 | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 46/163 reads (28%) | catalogued as COSV99211204; called by muse, mutect2, varscan2
- RBFOX1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1159465610, COSV60951662; called by muse, mutect2, varscan2
- RHOT1 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as rs769181876, COSV100447096, COSV61714689; called by muse, mutect2, varscan2
- RPF2 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs150251680, COSV64369933; called by muse, mutect2, varscan2
- SALL1 | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs769014673, COSV51755641; called by muse, mutect2, varscan2
- SCAI | c.1129C>T p.R377C (on ENST00000336505 / NM_001144877.3; = p.R400C on NM_173690.5) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs760144612, COSV60614686; called by muse, mutect2, varscan2
- SELP | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV55254687, COSV99740828; called by muse, mutect2, varscan2
- SEMA3F | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773078256, COSV50031790; called by muse, mutect2, varscan2
- SLC1A3 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs750317354, COSV54318200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLFN12 | c.817del p.V273Cfs*11 | Frame Shift Del (DEL) | VAF 37/162 reads (23%) | catalogued as COSV59226735; called by mutect2, pindel, varscan2
- SOX10 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV61005703; called by muse, mutect2, varscan2
- SOX30 | c.1758T>G p.I586M | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV99398328; called by muse, mutect2, varscan2
- SPEG | c.4750G>A p.E1584K | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); catalogued as rs979095702, COSV56674044; called by muse, mutect2, varscan2
- THSD7B | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV55734680; called by muse, mutect2, varscan2
- TMEM108 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.295); catalogued as rs765133057, COSV58863874; called by muse, mutect2, varscan2
- TMEM255B | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV64713884; called by muse, mutect2, varscan2
- USH2A | c.12424C>T p.H4142Y | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.188); catalogued as rs759071552, COSV56397215; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV57639250; called by muse, mutect2, varscan2
- FBLN5 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- IGHV3-20 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PARP9 | c.24_27delinsGGC p.A10Qfs*65 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | called by pindel, varscan2*
- THSD7B | c.2208dup p.D737Rfs*9 | Frame Shift Ins (INS) | VAF 86/251 reads (34%) | called by mutect2, pindel, varscan2
- ALDH1L2 | c.1425C>T p.S475= | Silent (SNP) | VAF 63/121 reads (52%) | catalogued as COSV51557592; called by muse, mutect2, varscan2
- APEH | c.1725C>T p.H575= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV56535157; called by muse, mutect2, varscan2
- C12orf50 | c.1068G>T p.T356= | Silent (SNP) | VAF 51/228 reads (22%) | catalogued as rs201866729, COSV53895517, COSV53896910, COSV53897309; called by muse, mutect2, varscan2
- CACNG4 | c.597C>T p.G199= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs142496896; called by muse, mutect2, varscan2
- CCDC158 | c.549G>A p.E183= | Silent (SNP) | VAF 86/167 reads (51%) | catalogued as COSV66355444, COSV66356611; called by muse, mutect2, varscan2
- DNAH1 | c.4530C>T p.N1510= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs758327285, COSV70231932; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM6 | c.1263G>A p.A421= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs377464746; called by muse, mutect2, varscan2
- HMCN1 | c.12762G>A p.L4254= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as COSV54916902; called by muse, mutect2, varscan2
- HPDL | c.543C>T p.H181= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs866965472, COSV58344581; called by muse, mutect2, varscan2
- ITGBL1 | c.771G>A p.P257= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs145784947; called by muse, mutect2, varscan2
- MAFB | c.732G>A p.R244= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- MMP9 | c.612C>T p.F204= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV63434237; called by muse, mutect2, varscan2
- OR2T33 | c.531C>T p.C177= | Silent (SNP) | VAF 170/333 reads (51%) | catalogued as rs746857030, COSV58815948; called by muse, mutect2, varscan2
- OR3A1 | c.207A>G p.L69= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as rs530368229, COSV60163441; called by muse, mutect2, varscan2
- PCARE | c.1578G>A p.Q526= | Silent (SNP) | VAF 178/381 reads (47%) | catalogued as COSV59055974; called by muse, mutect2, varscan2
- PFKFB3 | c.213C>T p.V71= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs374201933, COSV57994241; called by muse, mutect2, varscan2
- PRMT2 | c.423C>T p.I141= | Silent (SNP) | VAF 72/121 reads (60%) | catalogued as rs763946678, COSV52456234; called by muse, mutect2, varscan2
- TPSAB1 | c.225C>T p.C75= | Silent (SNP) | VAF 98/306 reads (32%) | catalogued as rs370737397, COSV58782384; called by muse, mutect2, varscan2
- TSPEAR | c.1140C>T p.I380= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs781813611, COSV59953257; called by muse, mutect2, varscan2
- TYROBP | c.138C>T p.I46= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs760363848, COSV52888159; called by muse, mutect2, varscan2
